Somatic mutation profile of tumor specimen TARGET-30-PASTGH-09A (aliquot TARGET-30-PASTGH-09A-01D) from TARGET case TARGET-30-PASTGH, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 18.6 years (6,800 days).
Specimen TARGET-30-PASTGH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a79f8a03-40e6-4c6a-b966-a7e9d0d5f77b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASTGH-10A (Blood Derived Normal), aliquot TARGET-30-PASTGH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23bfae16-e03d-4869-a3d2-08fa5c111d12

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.4389G>C p.Q1463H | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.556); catalogued as COSV51647750; called by muse, mutect2, varscan2
- ATRX | c.869del p.L290Cfs*9 | Frame Shift Del (DEL) | VAF 39/115 reads (34%) | called by mutect2, pindel, varscan2
- DNAH9 | c.5029G>C p.E1677Q | Missense Mutation (SNP) | VAF 5/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KMT5B | c.1661T>G p.I554S | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH4 | c.3789A>G p.I1263M | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- CCDC168 | c.11269C>T p.L3757= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as COSV59422244, COSV59424644; called by muse, mutect2, varscan2
- POLR2A | c.-144del | 5'UTR (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
